Gene-level copy-number profile of tumor specimen MP2PRT-PATJIU-TMP1-A from MP2PRT case MP2PRT-PATJIU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,113 days).
Specimen MP2PRT-PATJIU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d3541eb4-4031-4757-be32-98b99c845f13.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATJIU-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/acea9580-287e-4bf1-82cf-a95d7a991b3f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 2,121; copy number 2: 44,243; copy number 3: 12,484.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 35 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:113,432,600–113,436,042, 1 gene: AC016745.2.
- chr14:106,586,376–106,637,973, 12 genes (within-gene range 0–2): IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,609. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
